Somatic mutation profile of tumor specimen TCGA-DU-A76O-01A (aliquot TCGA-DU-A76O-01A-11D-A32B-08) from TCGA case TCGA-DU-A76O, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 30.0 years (10,960 days).
Specimen TCGA-DU-A76O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c625276b-0763-4593-90fb-05a9496593c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A76O-10A (Blood Derived Normal), aliquot TCGA-DU-A76O-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57261b1c-a8cf-448d-94ff-18dbf75f369c

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Splice Site 1, RNA 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | hotspot (GDC flag); catalogued as COSV64870748; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 21/24 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARFIP2 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749729590, COSV99601683; called by muse, mutect2, varscan2
- ATRX | c.5371G>T p.D1791Y | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971469, COSV64885960; called by muse, mutect2, varscan2
- ATRX | c.4700G>A p.G1567D | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969985; called by muse, mutect2
- BFSP2 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100183954; called by muse, mutect2, varscan2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, mutect2
- FAAP100 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372340384; called by muse, mutect2, varscan2
- SPAST | c.1494-2A>T p.X498_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | catalogued as CD023280, CS011849, CS107590, COSV59513646; called by muse, mutect2
- SPESP1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV99534796; called by muse, mutect2, varscan2
- SPG11 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99969684; called by muse, mutect2, varscan2
- SULT1A2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs772334533, COSV57681222; called by muse, varscan2
- SULT1A2 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145465524; called by muse, varscan2
- TIAM2 | c.1705T>C p.F569L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100020181; called by muse, mutect2
- TMEM150A | c.665A>G p.Y222C (on ENST00000334462 / NM_001031738.3; = p.Y169C on NM_153342.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777802848, COSV100110615; called by muse, mutect2, varscan2
- TTN | c.9672G>T p.R3224S (on ENST00000591111; = p.R3178S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | PolyPhen benign (0.116); catalogued as COSV100630501, COSV59906165; called by muse, mutect2, varscan2
- ZNF503 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as rs1486126962, COSV100998044; called by muse, mutect2, varscan2
- AFF3 | c.648T>C p.F216= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV100420125; called by muse, mutect2, varscan2
- PELO | c.741C>T p.S247= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs1490441743, COSV99252182; called by muse, mutect2, varscan2
- SLC35G3 | c.54G>A p.P18= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs539353698, COSV52012001; called by muse, mutect2, varscan2
- TRIM11 | c.570A>T p.A190= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99489020; called by muse, mutect2
- AL109984.1 | n.186+1338G>A | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100802072; called by muse, mutect2, varscan2
- SNORD115-14 | n.6G>T | RNA (SNP) | VAF 32/250 reads (13%) | called by muse, mutect2, varscan2
